Gene-level copy-number profile of specimen HCM-BROD-0793-C15-85M from HCMI case HCM-BROD-0793-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.2 years (20,179 days).
Specimen HCM-BROD-0793-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f8689fe2-afc1-4ec5-9034-52825310b6ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0793-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/aeb2171a-cbf2-4ab0-943d-97f813b01ec4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 316; copy number 1: 3,009; copy number 2: 14,480; copy number 3: 24,598; copy number 4: 11,045; copy number 5: 3,777; copy number 6: 860; copy number 7: 161; copy number 8: 114; copy number 9: 20; copy number 10: 118; copy number 11: 4; copy number 13: 52; copy number 14: 1; copy number 16: 90; copy number 18: 142; copy number 21: 37; copy number 22: 3; copy number 32: 60; copy number 103: 10; copy number 278: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 820 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,111,815–15,449,242, 11 genes, copy number 7 (within-gene range 4–7): TMEM51-AS1, TMEM51, C1orf195, MFFP1, ZBTB2P1, FHAD1, FHAD1-AS1, AL031283.2, AL031283.1, EFHD2, CTRC.
- chr1:15,617,458–15,786,594, 9 genes, copy number 7–8: DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1.
- chr1:39,944,890–39,944,998, 1 gene, copy number 7: Y_RNA.
- chr1:120,489,860–120,842,110, 5 genes, copy number 8 (within-gene range 2–8): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26.
- chr5:33,424,025–38,608,354, 90 genes, copy number 8–11 (within-gene range 6–11) (broad region; genes not listed).
- chr5:38,557,502–38,557,561, 1 gene, copy number 8 (within-gene range 6–8): MIR3650.
- chr5:162,761,833–162,762,313, 1 gene, copy number 7: ARL2BPP5.
- chr7:53,926,676–57,074,664, 91 genes, copy number 8–13 (broad region; genes not listed).
- chr8:2,935,353–8,049,267, 122 genes, copy number 8–21 (broad region; genes not listed).
- chr8:8,086,022–8,116,949, 4 genes, copy number 10: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:8,701,937–12,318,316, 113 genes, copy number 16–22 (broad region; genes not listed).
- chr11:69,438,365–69,819,416, 9 genes, copy number 7: AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:70,056,230–70,189,528, 5 genes, copy number 7 (within-gene range 6–7): LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2.
- chr11:70,467,856–71,252,577, 1 gene, copy number 7 (within-gene range 6–7): SHANK2.
- chr11:70,626,441–70,635,658, 1 gene, copy number 7 (within-gene range 6–7): SHANK2-AS1.
- chr11:70,862,790–70,896,305, 3 genes, copy number 7: SHANK2-AS3, MIR3664, AP003783.1.
- chr11:73,400,487–73,598,189, 1 gene, copy number 7 (within-gene range 6–7): FAM168A.
- chr11:73,510,658–75,206,549, 62 genes, copy number 7 (broad region; genes not listed).
- chr11:111,040,098–111,308,735, 9 genes, copy number 7: RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2.
- chr11:111,352,255–111,766,389, 15 genes, copy number 7: POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B.
- chr11:111,874,056–112,022,653, 11 genes, copy number 7 (within-gene range 6–7): FDXACB1, C11orf1, RPL37AP8, CRYAB, HSPB2, HSPB2-C11orf52, C11orf52, DIXDC1, RNA5SP351, AP000907.1, AP000907.2.
- chr12:14,365,632–28,581,511, 225 genes, copy number 14–278 (broad region; genes not listed).
- chr12:30,861,921–30,862,179, 1 gene, copy number 7: PPIAP44.
- chr18:22,933,349–23,982,556, 16 genes, copy number 7–11 (within-gene range 3–11): MIR4741, RN7SL745P, Y_RNA, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1.
- chr18:39,016,047–39,800,322, 8 genes, copy number 7 (within-gene range 6–7): RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2.
- chr18:39,841,174–40,144,504, 5 genes, copy number 7: LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45.

Autosomal genes at a single copy (total copy number 1): 469. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
